Surgical pathology report (de-identified scan), TCGA case TCGA-G2-AA3C, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-AA3C-01A (Primary Tumor).

2200-3
Carcinoma, urothelial NOS 8/20/13
Site: Bladder NOS C67.9
8/21/14

DIAGNOSIS

(A) BLADDER TUMOR:

UROTHELIAL CARCINOMA WITH SARCOMATOID DIFFERENTIATION, HIGH
GRADE (GRADE 3), EXTENSIVELY INVOLVING MOST TISSUE FRAGMENTS.

UROTHELIAL CARCINOMA IN-SITU.

GROSS DESCRIPTION

(A) BLADDER TUMOR - Multiple irregular fragments of white-tan soft
tissue, 2.0 x 2.0 x 0.8 cm in aggregate. Entirely submitted in A1 and A2.

CLINICAL HISTORY

Bladder cancer.

Source: NCI Genomic Data Commons file aad22e64-49d0-4dbc-8de5-f6ee1e99c83c (TCGA-G2-AA3C.B1E681AE-43AC-4E17-B334-3ACC476DC289.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).